Somatic mutation profile of tumor specimen TCGA-HC-8261-01B (aliquot TCGA-HC-8261-01B-05D-2298-08) from TCGA case TCGA-HC-8261, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 48.9 years (17,874 days).
Specimen TCGA-HC-8261-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d81fcf25-aaf4-4d34-8f56-1beb74c84236.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8261-10A (Blood Derived Normal), aliquot TCGA-HC-8261-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b2f845d-56df-4ddd-803d-cb55cb508dfb

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCHS1 | c.3691C>G p.P1231A | Missense Mutation (SNP) | VAF 24/728 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55035644; called by muse, mutect2
- TTC6 | c.1127C>T p.T376I (on ENST00000267368; = p.T1742I on NM_001310135.3) | Missense Mutation (SNP) | VAF 22/600 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1327166670, COSV57448916; called by muse, mutect2
